Somatic mutation profile of tumor specimen MP2PRT-PAVFHA-TMP1-A (aliquot MP2PRT-PAVFHA-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVFHA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 6.2 years (2,249 days).
Specimen MP2PRT-PAVFHA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50b56008-e24f-42d9-a392-e205e89cdf2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFHA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFHA-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1aba6ba-3b8f-4e38-bdad-fd10bd2d62c0

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 117/251 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.3739G>A p.A1247T (on ENST00000398564; = p.A1222T on NM_014629.4) | Missense Mutation (SNP) | VAF 217/671 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs576755623, COSV50644511; called by muse, mutect2, varscan2
- ATP10A | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 164/338 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs1205352747, COSV63518856; called by muse, mutect2, varscan2
- HCN4 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370442588, COSV99983260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAA15 | c.1896T>G p.D632E | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs759801535; called by muse, mutect2, varscan2
- NCKIPSD | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 116/260 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs139058555; called by muse, mutect2, varscan2
- SRRM2 | c.1356G>T p.E452D | Missense Mutation (SNP) | VAF 160/301 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs767108797; called by muse, mutect2, varscan2
- TMEM44 | c.1235C>T p.S412L (on ENST00000392432 / NM_001166305.2; = p.S365L on NM_138399.5) | Missense Mutation (SNP) | VAF 199/351 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); catalogued as rs373869816; called by muse, mutect2, varscan2
- UNK | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs374562823; called by mutect2, varscan2
- RGS7 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.4855G>T p.V1619L | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TRGJP1 | chr7:38276314 GGTATCACACCGGTCTA>CCGAGG | Missense Mutation (DEL) | VAF 30/32 reads (94%) | called by pindel, varscan2*
- EML3 | c.1575C>T p.D525= | Silent (SNP) | VAF 226/426 reads (53%) | catalogued as rs575047153; called by muse, mutect2, varscan2
- H4C9 | c.246C>T p.V82= | Silent (SNP) | VAF 152/486 reads (31%) | catalogued as COSV62890268; called by muse, mutect2, varscan2
